Somatic mutation profile of tumor specimen TCGA-19-1787-01B (aliquot TCGA-19-1787-01B-01W-0922-08) from TCGA case TCGA-19-1787, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 49.0 years (17,894 days).
Specimen TCGA-19-1787-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4240a236-7f1a-42b7-b74d-ea523e7de149.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-1787-10A (Blood Derived Normal), aliquot TCGA-19-1787-10A-01D-1495-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/210ed92f-448c-4b67-942d-c9c41d7ced06

The open-access MAF lists 645 somatic variants for this specimen: 464 protein-altering or splice-affecting, 173 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 392, Silent 173, Frame Shift Del 23, Nonsense Mutation 20, Frame Shift Ins 9, In Frame Del 9, Splice Region 6, Splice Site 5, Intron 4, 3'UTR 2, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB11 | c.3457C>T p.R1153C | Missense Mutation (SNP) | VAF 87/114 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs72549395, CM980251, COSV99791363; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 36/70 reads (51%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- CCDC39 | c.286C>T p.R96* | Nonsense Mutation (SNP) | VAF 32/45 reads (71%) | catalogued as rs778577109; ClinVar: pathogenic; called by muse, varscan2
- PCDH12 | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 22/114 reads (19%) | catalogued as rs370283860; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.2350_2351del p.F784Hfs*14 (on ENST00000303395 / NM_001202435.3; = p.F773Hfs*14 on NM_006920.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 37/126 reads (29%) | catalogued as rs1553543215; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- TGM1 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121918718, CM014104, CM951202, COSV52866401; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 196/250 reads (78%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AADACL4 | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 185/230 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs376400654, COSV66106145; called by muse, mutect2, varscan2
- ABCB8 | c.962G>A p.R321H (on ENST00000297504 / NM_001282291.2; = p.R304H on NM_007188.5) | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as rs758830222, COSV99873580; called by muse, mutect2, varscan2
- ABCC8 | c.2318C>T p.S773L | Missense Mutation (SNP) | VAF 29/247 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as rs1355146733, COSV56846265; called by muse, mutect2, varscan2
- ACAD10 | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.392); catalogued as rs144623113; called by muse, mutect2, varscan2
- ACAD10 | c.2893G>A p.V965M | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.305); catalogued as rs751601129, COSV100563727, COSV58153854; called by muse, mutect2, varscan2
- ACAP2 | c.1210C>T p.R404W | Missense Mutation (SNP) | VAF 304/399 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1466971128, COSV100461310; called by muse, mutect2, varscan2
- ACTN4 | c.2083C>T p.R695C | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as rs769829818, COSV53142775; called by muse, mutect2, varscan2
- ACVR1 | c.1010T>C p.L337S | Missense Mutation (SNP) | VAF 64/93 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99717400; called by muse, mutect2, varscan2
- ADAMTS19 | c.3153G>A p.W1051* | Nonsense Mutation (SNP) | VAF 21/171 reads (12%) | catalogued as COSV99176204; called by muse, mutect2, varscan2
- ADAMTS5 | c.2095G>A p.V699I | Missense Mutation (SNP) | VAF 371/1047 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs374203818; called by muse, mutect2, varscan2
- ADCY1 | c.3283G>A p.V1095I | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.006); catalogued as rs763670732, COSV52041109; called by muse, mutect2, varscan2
- ADGRB2 | c.3283G>A p.G1095R | Missense Mutation (SNP) | VAF 37/55 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1275448736, COSV57070488, COSV99926612; called by muse, mutect2, varscan2
- ADGRF5 | c.884A>G p.K295R | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV99344720; called by muse, mutect2, varscan2
- ADGRV1 | c.17921C>T p.A5974V | Missense Mutation (SNP) | VAF 75/605 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV101315362; called by muse, mutect2, varscan2
- ADRA2C | c.373G>A p.G125S | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0.05); PolyPhen benign (0.107); catalogued as COSV100342408; called by muse, mutect2, varscan2
- AHNAK | c.17210C>G p.S5737C | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778764748, COSV57222793, COSV99945259; called by muse, mutect2, varscan2
- AHSA1 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 197/278 reads (71%) | SIFT tolerated (0.07); PolyPhen benign (0.142); catalogued as rs766778621, COSV53632674, COSV99375806; called by muse, mutect2, varscan2
- AKAP17A | c.143A>G p.N48S | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as rs762268432; called by muse, mutect2
- AMPD1 | c.1031A>G p.N344S | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as COSV100814787; called by muse, mutect2
- AMPD3 | c.311C>T p.P104L (on ENST00000396553 / NM_001025389.2; = p.P113L on NM_000480.3) | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs770661067, COSV67330791; called by muse, mutect2, varscan2
- ANGPTL2 | c.1363G>A p.G455R | Missense Mutation (SNP) | VAF 191/290 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200073434, COSV99400593; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7177G>A p.A2393T | Missense Mutation (SNP) | VAF 137/224 reads (61%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.024); catalogued as rs754457986, COSV99781812; called by muse, mutect2, varscan2
- ANKRD30A | c.2844G>A p.M948I (on ENST00000611781; = p.M892I on NM_052997.2) | Missense Mutation (SNP) | VAF 67/108 reads (62%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64605965, COSV64619278; called by muse, mutect2, varscan2
- APBA2 | c.1606G>A p.E536K | Missense Mutation (SNP) | VAF 17/19 reads (89%) | SIFT tolerated (0.07); PolyPhen benign (0.124); catalogued as COSV101258120, COSV101258206; called by muse, mutect2, varscan2
- ARAP3 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs144772220; called by muse, mutect2, varscan2
- ARHGAP39 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 101/130 reads (78%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as rs559110879, COSV99430124; called by muse, mutect2, varscan2
- ARMCX2 | c.907G>C p.E303Q | Missense Mutation (SNP) | VAF 13/384 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.515); catalogued as COSV100168223, COSV57529518; called by muse, mutect2
- ASIC5 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 66/80 reads (83%) | SIFT tolerated (0.16); PolyPhen benign (0.219); catalogued as rs144591256; called by muse, mutect2, varscan2
- ATF2 | c.617G>T p.R206M | Missense Mutation (SNP) | VAF 72/192 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as COSV51376528; called by muse, mutect2, varscan2
- ATG13 | c.601T>A p.F201I | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV100365445; called by muse, mutect2, varscan2
- ATG9A | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as rs1413942878, COSV100036683; called by muse, mutect2, varscan2
- ATP10B | c.3787C>G p.L1263V | Missense Mutation (SNP) | VAF 227/415 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV100513926, COSV59146822; called by muse, mutect2, varscan2
- ATRX | c.5408G>A p.R1803H | Missense Mutation (SNP) | VAF 167/207 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64873488; called by muse, mutect2, varscan2
- BCL3 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs780503593, COSV99377926; called by muse, mutect2, varscan2
- BMS1 | c.1982C>T p.T661M | Missense Mutation (SNP) | VAF 122/187 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs201989025; called by muse, mutect2, varscan2
- BMT2 | c.739_741del p.L247del | In Frame Del (DEL) | VAF 22/67 reads (33%) | catalogued as rs1241468183; called by pindel, varscan2
- BRD1 | c.2254C>T p.R752* | Nonsense Mutation (SNP) | VAF 10/17 reads (59%) | catalogued as COSV53462357; called by muse, mutect2, varscan2
- BRF2 | c.673G>A p.V225I | Missense Mutation (SNP) | VAF 28/36 reads (78%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs778374531, COSV99604663; called by muse, mutect2, varscan2
- BRWD1 | c.3781A>G p.I1261V | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.152); catalogued as COSV100312646; called by muse, mutect2, varscan2
- C10orf71 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 153/230 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs375624849; called by muse, mutect2, varscan2
- C16orf70 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 60/81 reads (74%) | catalogued as rs763179851, COSV99531060; called by muse, mutect2, varscan2
- C18orf54 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as rs760888628, COSV100266275; called by muse, mutect2, varscan2
- C6 | c.1751C>T p.S584L | Missense Mutation (SNP) | VAF 74/230 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.411); catalogued as rs763257632, COSV54704717; called by muse, mutect2, varscan2
- C7 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs755950201, COSV100495266, COSV57482404; called by muse, mutect2, varscan2
- CACNA1G | c.4390C>T p.R1464W | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV61728654; called by muse, mutect2, varscan2
- CACYBP | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 46/72 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); catalogued as rs1430522161, COSV100871593; called by muse, mutect2, varscan2
- CAMKK2 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.153); catalogued as rs374616967; called by muse, mutect2
- CAPN6 | c.1841G>A p.R614H | Missense Mutation (SNP) | VAF 238/297 reads (80%) | SIFT tolerated (0.13); PolyPhen benign (0.16); catalogued as rs201824799, COSV100137032, COSV60697635; called by muse, varscan2
- CASZ1 | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs754266033, COSV59741008; called by muse, mutect2, varscan2
- CBLIF | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 181/244 reads (74%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs150639344; called by muse, mutect2, varscan2
- CCDC60 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 160/319 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.555); catalogued as rs144745942; called by muse, mutect2, varscan2
- CCDC63 | c.1630C>T p.R544C | Missense Mutation (SNP) | VAF 91/168 reads (54%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.453); catalogued as rs774381462, COSV99960542; called by muse, mutect2, varscan2
- CCDC9 | c.4-1G>A p.X2_splice | Splice Site (SNP) | VAF 85/114 reads (75%) | catalogued as COSV55719818; called by muse, mutect2, varscan2
- CCHCR1 | c.1601G>A p.R534Q | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as rs373003491; called by muse, mutect2, varscan2
- CCL22 | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 172/234 reads (74%) | SIFT tolerated (0.26); PolyPhen benign (0.067); catalogued as rs748315767, COSV54659863; called by muse, mutect2, varscan2
- CD34 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 177/229 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs768640209, COSV100178078; called by muse, mutect2, varscan2
- CDH3 | c.461dup p.E155* | Frame Shift Ins (INS) | VAF 6/38 reads (16%) | catalogued as rs1437616632; called by mutect2, varscan2
- CDH8 | c.2094G>T p.K698N | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as COSV54856898; called by muse, mutect2
- CDRT1 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs570653295, COSV99887425; called by muse, mutect2, varscan2
- CDX1 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs756165293, COSV99199296; called by muse, mutect2
- CELA3B | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1231345290, COSV100448843; called by muse, mutect2
- CEMIP2 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 121/160 reads (76%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs1449413534, COSV65485644; called by muse, mutect2, varscan2
- CENPK | c.717G>A p.W239* | Nonsense Mutation (SNP) | VAF 20/200 reads (10%) | catalogued as COSV99669389; called by muse, mutect2, varscan2
- CES3 | c.1129G>A p.V377I | Missense Mutation (SNP) | VAF 19/21 reads (90%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs778131714, COSV57592676; called by muse, mutect2, varscan2
- CHMP2A | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 66/83 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV99447871; called by muse, mutect2, varscan2
- CHRNB4 | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 35/52 reads (67%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs375172518; called by muse, mutect2, varscan2
- CHRNB4 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 84/112 reads (75%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs372392383; called by muse, varscan2
- CIITA | c.3223C>T p.R1075W | Missense Mutation (SNP) | VAF 137/183 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141713994; called by muse, mutect2, varscan2
- CLEC1A | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 76/163 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.74); catalogued as rs763900321, COSV59532733; called by muse, mutect2, varscan2
- CLUH | c.3400A>G p.S1134G (on ENST00000435359; = p.S1173G on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV101425601; called by muse, mutect2, varscan2
- CNMD | c.71del p.P24Rfs*6 | Frame Shift Del (DEL) | VAF 13/28 reads (46%) | catalogued as rs768157613; called by mutect2, pindel, varscan2
- CNTN3 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1418842277, COSV55164966, COSV55169547; called by muse, mutect2, varscan2
- COL16A1 | c.3150C>T p.I1050= | Splice Region (SNP) | VAF 18/22 reads (82%) | catalogued as rs368007133, COSV54705941; called by muse, mutect2, varscan2
- COL22A1 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 51/78 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100275773, COSV99072279; called by muse, mutect2, varscan2
- CROCC | c.5384G>A p.R1795Q | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.082); catalogued as rs527905568, COSV100977578; called by muse, mutect2, varscan2
- CSMD2 | c.1387G>A p.G463S | Missense Mutation (SNP) | VAF 279/357 reads (78%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs773143736, COSV53891996; called by muse, mutect2, varscan2
- CXADR | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 71/201 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs768087388, COSV53028856; called by muse, mutect2, varscan2
- CXXC1 | c.1660C>T p.R554W | Missense Mutation (SNP) | VAF 78/250 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV53274753; called by muse, mutect2, varscan2
- CYYR1 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 373/829 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as rs147481963; called by muse, mutect2, varscan2
- DCAF5 | c.2519G>A p.R840H | Missense Mutation (SNP) | VAF 74/98 reads (76%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.005); catalogued as rs201467372, COSV58463600; called by muse, mutect2, varscan2
- DCN | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.804); catalogued as rs755987970, COSV99271697; called by muse, mutect2, varscan2
- DDX54 | c.673G>A p.G225R | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs930376012, COSV100013538, COSV58376071; called by muse, mutect2, varscan2
- DENND1A | c.1183G>A p.A395T | Missense Mutation (SNP) | VAF 19/238 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as rs1446493210, COSV101010351; called by muse, mutect2
- DFFB | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 209/270 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs201973418, COSV100138594; called by muse, mutect2, varscan2
- DIS3L2 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 236/328 reads (72%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as rs754512238, COSV99805135; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DISP3 | c.3757G>A p.V1253I | Missense Mutation (SNP) | VAF 22/29 reads (76%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as rs200620988; called by muse, mutect2, varscan2
- DNAH10 | c.3970G>A p.G1324R (on ENST00000409039; = p.G1263R on NM_207437.3) | Missense Mutation (SNP) | VAF 201/419 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as COSV101291886; called by muse, mutect2, varscan2
- DNAH10 | c.5233G>A p.A1745T (on ENST00000409039; = p.A1684T on NM_207437.3) | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.104); catalogued as rs1345042500, COSV68996611; called by muse, mutect2, varscan2
- DNAH11 | c.7472G>A p.R2491H | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs369438218, COSV100176418; ClinVar: uncertain significance; called by muse, mutect2
- DNAH17 | c.1702G>T p.A568S | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV101101198; called by muse, mutect2, varscan2
- DNAH7 | c.11908C>T p.R3970W | Missense Mutation (SNP) | VAF 100/133 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs955699383, COSV100413546; called by muse, mutect2, varscan2
- DOCK1 | c.2251C>T p.R751C | Missense Mutation (SNP) | VAF 116/169 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as rs999910753, COSV99726406; called by muse, mutect2, varscan2
- DOCK1 | c.3782G>A p.R1261Q | Missense Mutation (SNP) | VAF 150/201 reads (75%) | SIFT tolerated (0.38); PolyPhen benign (0.103); catalogued as rs765684085, COSV99726407; called by muse, mutect2, varscan2
- DOCK4 | c.3602G>A p.R1201H | Missense Mutation (SNP) | VAF 229/516 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs181180606; called by muse, mutect2, varscan2
- DOCK8 | c.2296G>A p.E766K | Missense Mutation (SNP) | VAF 64/93 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs267602235, COSV101210002; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DPH2 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs140036435; called by muse, mutect2, varscan2
- DR1 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.03); catalogued as rs375320336, COSV64725501; called by muse, mutect2
- DSP | c.1840G>A p.D614N | Missense Mutation (SNP) | VAF 146/207 reads (71%) | SIFT tolerated (0.18); PolyPhen benign (0.117); catalogued as rs764951792, COSV65792074; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYNC1I1 | c.1859G>A p.R620Q | Missense Mutation (SNP) | VAF 184/436 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as rs767986943, COSV61473139, COSV61474168; called by muse, mutect2, varscan2
- E2F7 | c.656T>C p.L219P | Missense Mutation (SNP) | VAF 36/209 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100523242; called by muse, mutect2, varscan2
- EHF | c.793C>T p.R265* | Nonsense Mutation (SNP) | VAF 74/110 reads (67%) | catalogued as COSV57668023, COSV99140841; called by muse, mutect2, varscan2
- EIF4G1 | c.4375C>T p.R1459W (on ENST00000346169 / NM_198241.3; = p.R1264W on NM_004953.5) | Missense Mutation (SNP) | VAF 78/107 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs564880447, COSV59995870; called by muse, mutect2, varscan2
- ELK3 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs752081794, COSV57387626; called by muse, mutect2, varscan2
- ELN | c.484G>A p.G162S | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs139718810, COSV52715443; called by muse, mutect2, varscan2
- ELP5 | c.53T>G p.L18W | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100020874; called by muse, mutect2, varscan2
- ENPEP | c.347C>T p.T116M | Missense Mutation (SNP) | VAF 377/497 reads (76%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV54448526, COSV99486896; called by muse, mutect2, varscan2
- EP400 | c.1570G>A p.A524T | Missense Mutation (SNP) | VAF 110/315 reads (35%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs549514087, COSV100200171; called by muse, mutect2, varscan2
- EPS8 | c.1475C>T p.A492V | Missense Mutation (SNP) | VAF 171/324 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs752774580, COSV99842490; called by muse, mutect2, varscan2
- ERBB3 | c.1739G>A p.R580Q | Missense Mutation (SNP) | VAF 184/319 reads (58%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as rs200350558, COSV57247479; called by muse, mutect2, varscan2
- ESPL1 | c.4409G>A p.R1470H | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as rs749013341, COSV99228769; called by muse, mutect2, varscan2
- ESPL1 | c.5602C>T p.R1868* | Nonsense Mutation (SNP) | VAF 225/511 reads (44%) | catalogued as COSV99228772; called by muse, mutect2, varscan2
- ESRP2 | c.1103C>T p.S368L (on ENST00000565858 / NM_001365264.1; = p.S358L on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0.05); PolyPhen benign (0.322); catalogued as rs763741902, COSV52174036; called by muse, mutect2, varscan2
- EVPL | c.5627G>A p.R1876H | Missense Mutation (SNP) | VAF 45/81 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs748273790, COSV100043768; called by muse, varscan2
- F13A1 | c.1621C>T p.R541W | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs1396045292, COSV53563222; called by muse, varscan2
- FADS1 | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 70/106 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1380250440, COSV100650181; called by muse, mutect2, varscan2
- FAM168B | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 241/335 reads (72%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.006); catalogued as rs1358356358, COSV101112206; called by muse, mutect2, varscan2
- FAM90A1 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.34); catalogued as rs780112980, COSV100274146; called by muse, mutect2, varscan2
- FAT1 | c.12041C>T p.T4014M | Missense Mutation (SNP) | VAF 94/144 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0.277); catalogued as rs760053140, COSV71674331; called by muse, mutect2, varscan2
- FBLN2 | c.2575G>A p.V859M | Missense Mutation (SNP) | VAF 35/49 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs376360301; called by muse, mutect2, varscan2
- FBXL7 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs1437379180, COSV100308860; called by muse, mutect2, varscan2
- FCGR3A | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs370288605; called by muse, mutect2, varscan2
- FCGR3B | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs375134752, COSV54211106; called by muse, mutect2, varscan2
- FER1L6 | c.3327C>T p.H1109= | Splice Region (SNP) | VAF 125/193 reads (65%) | catalogued as rs779747501, COSV67551187; called by muse, mutect2, varscan2
- FERD3L | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 123/256 reads (48%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs866406481, COSV51762348; called by muse, mutect2, varscan2
- FGF20 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 71/95 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1325559004, COSV51662026; called by muse, mutect2, varscan2
- FGF6 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as rs199938701, COSV99960112; called by muse, mutect2, varscan2
- FHOD3 | c.3997G>A p.V1333I (on ENST00000359247 / NM_001281739.3; = p.V1350I on NM_025135.5) | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs149906669; called by muse, mutect2, varscan2
- FIGNL1 | c.1909C>T p.R637* | Nonsense Mutation (SNP) | VAF 36/69 reads (52%) | catalogued as rs754841480, COSV100794817, COSV100794893; called by muse, mutect2, varscan2
- FLG | c.3844G>A p.D1282N | Missense Mutation (SNP) | VAF 150/206 reads (73%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs762020650, COSV64240193; called by muse, mutect2, varscan2
- FMR1NB | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 175/196 reads (89%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs145102389, COSV65071655; called by muse, mutect2, varscan2
- FNDC1 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 110/142 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774630537, COSV99794667; called by muse, mutect2, varscan2
- FNDC3B | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 96/132 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs371734932; called by muse, mutect2, varscan2
- FOXL2 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57727727; called by muse, mutect2, varscan2
- FOXP1 | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 97/124 reads (78%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs540360773, COSV59517465; called by muse, mutect2, varscan2
- FRMPD2 | c.2266+1G>A p.X756_splice | Splice Site (SNP) | VAF 3/31 reads (10%) | catalogued as COSV100563431; called by muse, mutect2
- FRMPD3 | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 200/235 reads (85%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.998); catalogued as rs1434750366, COSV99345448; called by muse, mutect2, varscan2
- FRY | c.5810G>A p.R1937H | Missense Mutation (SNP) | VAF 64/96 reads (67%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as rs897858265, COSV100968743; called by muse, mutect2, varscan2
- FRYL | c.7679G>A p.R2560Q | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs765228287, COSV99975416; called by muse, mutect2, varscan2
- GABRA1 | c.397A>G p.K133E | Missense Mutation (SNP) | VAF 96/143 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV99195680; called by muse, varscan2
- GAD1 | c.84G>A p.T28= | Splice Region (SNP) | VAF 6/13 reads (46%) | catalogued as rs566509021, COSV100713730; called by muse, mutect2, varscan2
- GAS2 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 139/200 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1229337785, COSV99534560; called by muse, mutect2, varscan2
- GCKR | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 62/93 reads (67%) | SIFT deleterious (0.04); PolyPhen benign (0.373); catalogued as rs146855458; called by muse, mutect2, varscan2
- GCN1 | c.5138G>A p.R1713H | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752134423, COSV100324533; called by muse, mutect2, varscan2
- GFRA2 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV60779688; called by muse, mutect2, varscan2
- GID8 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.061); catalogued as rs145315204; called by muse, mutect2, varscan2
- GJB3 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as rs759759043, COSV64904378; called by muse, mutect2, varscan2
- GLI1 | c.1487G>A p.R496H | Missense Mutation (SNP) | VAF 53/99 reads (54%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs759027001, COSV99953591, COSV99954496; called by muse, mutect2, varscan2
- GLI1 | c.1862G>A p.R621K | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.952); catalogued as COSV99953593; called by muse, mutect2, varscan2
- GMEB2 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 41/57 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99823370; called by muse, mutect2, varscan2
- GOSR2 | c.7C>T p.R3C (on ENST00000393456 / NM_001321134.1; = p.R21C on NM_004287.5) | Missense Mutation (SNP) | VAF 64/86 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs763366060, COSV56661245; called by muse, varscan2
- GPR155 | c.703C>T p.R235* | Nonsense Mutation (SNP) | VAF 22/38 reads (58%) | catalogued as rs375197307; called by muse, mutect2, varscan2
- GPR78 | c.811G>A p.V271M | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs201411082, COSV101223907; called by muse, mutect2, varscan2
- GRIN2B | c.1333A>G p.K445E | Missense Mutation (SNP) | VAF 137/279 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs1306964868, COSV101662866; called by muse, mutect2, varscan2
- GSTM1 | c.484G>T p.D162Y | Missense Mutation (SNP) | VAF 920/1074 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100564393; called by muse, mutect2, varscan2
- GTPBP6 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as rs752465951, COSV100397586; called by muse, mutect2, varscan2
- HECTD4 | c.4645C>T p.R1549C | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as rs776696918, COSV101106554; called by muse, mutect2, varscan2
- HECW2 | c.2914G>A p.D972N | Missense Mutation (SNP) | VAF 52/179 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53666824, COSV99645540; called by muse, mutect2, varscan2
- HELB | c.2999G>A p.W1000* | Nonsense Mutation (SNP) | VAF 177/350 reads (51%) | catalogued as COSV99921540; called by muse, mutect2, varscan2
- HELZ | c.4051G>A p.A1351T | Missense Mutation (SNP) | VAF 230/298 reads (77%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs759956817, COSV62378844; called by muse, mutect2, varscan2
- HIRA | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 82/122 reads (67%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs376487965; called by muse, mutect2, varscan2
- HK3 | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs529613291, COSV99457628; called by muse, mutect2, varscan2
- HOOK1 | c.1462C>T p.R488C | Missense Mutation (SNP) | VAF 302/390 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1160851673, COSV100968953; called by muse, mutect2, varscan2
- HS3ST5 | c.886C>T p.R296W | Missense Mutation (SNP) | VAF 58/81 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1207827920, COSV57143809; called by muse, mutect2, varscan2
- HSP90B1 | c.1669C>T p.R557* | Nonsense Mutation (SNP) | VAF 107/224 reads (48%) | catalogued as rs1323473420, COSV100236251; called by muse, mutect2, varscan2
- HTR1D | c.955G>A p.V319M | Missense Mutation (SNP) | VAF 108/131 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs567276499, COSV58447721; called by muse, mutect2, varscan2
- HTR5A | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs202028626, COSV55283429, COSV99072249; called by muse, mutect2, varscan2
- HYDIN | c.8095C>T p.R2699C | Missense Mutation (SNP) | VAF 162/229 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs760234450, COSV59271473; called by muse, mutect2, varscan2
- ICE1 | c.3916C>T p.R1306W | Missense Mutation (SNP) | VAF 33/45 reads (73%) | SIFT deleterious (0.04); PolyPhen benign (0.431); catalogued as rs890447534, COSV99663472; called by muse, mutect2, varscan2
- IGF1R | c.2215C>T p.R739W | Missense Mutation (SNP) | VAF 82/129 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs145300307, COSV51272964; called by muse, mutect2, varscan2
- IGF2BP1 | c.818+1G>A p.X273_splice | Splice Site (SNP) | VAF 302/471 reads (64%) | catalogued as rs1413532884, COSV51732557; called by muse, mutect2, varscan2
- IGFN1 | c.3053C>T p.T1018I (on ENST00000295591 / NM_001367841.1; = p.T3475I on NM_001164586.2) | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1323745019, COSV55170077; called by muse, mutect2, varscan2
- IGHMBP2 | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 21/22 reads (95%) | SIFT tolerated (0.09); PolyPhen benign (0.338); catalogued as rs752225738, COSV54821244; called by muse, mutect2, varscan2
- IK | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.885); catalogued as rs746748598, COSV70258310; called by muse, mutect2
- INPPL1 | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 51/67 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs769074650, COSV53360864; called by muse, mutect2, varscan2
- INSRR | c.3258G>T p.Q1086H | Missense Mutation (SNP) | VAF 25/31 reads (81%) | SIFT deleterious (0.05); PolyPhen benign (0.183); catalogued as rs1228357495, COSV100947035; called by muse, mutect2, varscan2
- INTS12 | c.1064C>T p.T355M | Missense Mutation (SNP) | VAF 243/340 reads (71%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); catalogued as rs748791802, COSV60861813; called by muse, mutect2, varscan2
- IPO8 | c.3004C>T p.R1002W | Missense Mutation (SNP) | VAF 404/1006 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs151232989; called by muse, mutect2, varscan2
- IQGAP2 | c.2599G>A p.D867N | Missense Mutation (SNP) | VAF 66/137 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV57169069; called by muse, mutect2, varscan2
- IRAK2 | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756857570, COSV99843578; called by muse, mutect2, varscan2
- ITGA11 | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 82/99 reads (83%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs189643766; called by muse, mutect2, varscan2
- ITGA2 | c.1687G>A p.D563N | Missense Mutation (SNP) | VAF 151/247 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99670021; called by muse, mutect2, varscan2
- KALRN | c.3209G>A p.R1070Q | Missense Mutation (SNP) | VAF 33/299 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99561725, COSV99564534; called by muse, mutect2, varscan2
- KAT6B | c.5704G>A p.A1902T | Missense Mutation (SNP) | VAF 221/358 reads (62%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV99767178; called by muse, mutect2, varscan2
- KATNAL2 | c.1007G>A p.R336Q (on ENST00000356157 / NM_001353899.1; = p.R264Q on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/163 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs200386880, COSV99795746; called by muse, mutect2, varscan2
- KCNH1 | c.263A>G p.E88G | Missense Mutation (SNP) | VAF 59/94 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.752); catalogued as COSV99656910; called by muse, mutect2, varscan2
- KCNMA1 | c.3209C>T p.P1070L (on ENST00000286628 / NM_001161352.2; = p.P1012L on NM_002247.4) | Missense Mutation (SNP) | VAF 113/155 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1364516204, COSV99694421; called by muse, mutect2, varscan2
- KCNQ2 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs756153757, COSV100609380; called by muse, mutect2, varscan2
- KDM1B | c.1105G>A p.V369M (on ENST00000449850; = p.V237M on NM_153042.4) | Missense Mutation (SNP) | VAF 51/74 reads (69%) | SIFT tolerated (0.05); PolyPhen benign (0.103); catalogued as rs750152791, COSV52810351; called by muse, mutect2, varscan2
- KDM5D | c.2108C>T p.T703M | Missense Mutation (SNP) | VAF 221/269 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100522125; called by muse, mutect2, varscan2
- KIAA0753 | c.2513G>A p.R838H | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as rs765004531, COSV100810515; called by muse, mutect2, varscan2
- KIF13B | c.2890G>A p.A964T | Missense Mutation (SNP) | VAF 37/48 reads (77%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs12549991, COSV72954281; called by muse, mutect2, varscan2
- KIF1B | c.4192G>T p.A1398S (on ENST00000377086 / NM_001365952.1; = p.A1352S on NM_015074.3) | Missense Mutation (SNP) | VAF 61/578 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV55809695, COSV99822268; called by muse, mutect2, varscan2
- KIF20A | c.506C>T p.T169M | Missense Mutation (SNP) | VAF 136/204 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200872203, COSV50145952; called by muse, mutect2, varscan2
- KIF20A | c.1553C>T p.P518L | Missense Mutation (SNP) | VAF 56/361 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.141); catalogued as COSV101203064; called by muse, mutect2, varscan2
- KIF4A | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 82/92 reads (89%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs779535123, COSV100979310; called by muse, mutect2, varscan2
- KIF5C | c.2810C>T p.T937M | Missense Mutation (SNP) | VAF 98/140 reads (70%) | SIFT deleterious (0.04); PolyPhen benign (0.378); catalogued as rs765950375, COSV68480336; called by muse, mutect2, varscan2
- KLHL3 | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 25/285 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100552808, COSV59056861; called by muse, mutect2, varscan2
- KLK6 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as rs200194649, COSV59565296; called by muse, mutect2, varscan2
- KNOP1 | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 57/93 reads (61%) | SIFT tolerated (0.42); PolyPhen benign (0.071); catalogued as rs374832937; called by muse, mutect2, varscan2
- KRTAP10-11 | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 110/298 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs779037491, COSV100551505, COSV100552400; called by muse, mutect2, varscan2
- KRTAP13-1 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs763603199, COSV100819897, COSV62663095; called by muse, mutect2, varscan2
- KRTAP3-3 | c.22G>A p.G8S | Missense Mutation (SNP) | VAF 285/431 reads (66%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.112); catalogued as rs746956366, COSV101195940; called by muse, mutect2, varscan2
- KSR2 | c.2101G>A p.E701K | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.76); catalogued as rs1390389754, COSV56682828; called by muse, varscan2
- LAMA1 | c.3346G>A p.G1116R | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs199554880, COSV101054665, COSV67531516; called by muse, mutect2, varscan2
- LAMA4 | c.4493G>A p.R1498H (on ENST00000230538 / NM_001105206.3; = p.R1491H on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/119 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.765); catalogued as rs147556641; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMB4 | c.5033G>A p.R1678H | Missense Mutation (SNP) | VAF 90/198 reads (45%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs759897739, COSV99222370; called by muse, mutect2, varscan2
- LARS1 | c.191C>T p.T64M | Missense Mutation (SNP) | VAF 50/83 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as rs370188134; called by muse, mutect2, varscan2
- LILRB2 | c.1021G>A p.V341M | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.743); catalogued as rs773342765, COSV100078905; called by muse, varscan2
- LILRB3 | c.1706C>G p.S569C (on ENST00000346401; = p.S557C on NM_006864.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99556886; called by muse, mutect2
- LINGO1 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); catalogued as COSV62436667; called by muse, mutect2, varscan2
- LINGO4 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs771985851, COSV100561762; called by muse, mutect2, varscan2
- LMCD1 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 95/115 reads (83%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.657); catalogued as COSV99337194; called by muse, mutect2, varscan2
- LSM11 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 18/354 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1229136418, COSV53847945; called by muse, mutect2
- MACROH2A2 | c.377C>T p.T126M | Missense Mutation (SNP) | VAF 52/70 reads (74%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as rs756338712, COSV100952288; called by muse, mutect2, varscan2
- MAML2 | c.2729G>A p.R910Q | Missense Mutation (SNP) | VAF 91/157 reads (58%) | SIFT tolerated (0.17); PolyPhen benign (0.215); catalogued as rs762982174, COSV73262774, COSV73262922; called by muse, mutect2, varscan2
- MARCHF4 | c.1096G>A p.G366S | Missense Mutation (SNP) | VAF 53/76 reads (70%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370447341; called by muse, mutect2, varscan2
- MCM7 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.999); catalogued as rs760332743, COSV57999434; called by muse, mutect2, varscan2
- MCPH1 | c.2048C>T p.T683M | Missense Mutation (SNP) | VAF 82/119 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758318947, COSV100765167; called by muse, mutect2, varscan2
- MED12 | c.6265C>T p.R2089W | Missense Mutation (SNP) | VAF 56/66 reads (85%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.265); catalogued as rs1210702033, COSV61344624; called by muse, mutect2, varscan2
- MED14 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 123/149 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as COSV100247254; called by muse, mutect2, varscan2
- MGLL | c.376G>A p.A126T (on ENST00000398104 / NM_001003794.2; = p.A136T on NM_007283.6) | Missense Mutation (SNP) | VAF 65/82 reads (79%) | SIFT tolerated (0.13); PolyPhen benign (0.238); catalogued as rs754071655, COSV54025880; called by muse, mutect2, varscan2
- MGMT | c.556G>A p.V186M (on ENST00000306010; = p.V155M on NM_002412.5) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.046); catalogued as rs753896761, COSV60029957; called by muse, mutect2, varscan2
- MIDEAS | c.535G>A p.V179M | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as rs1341406416, COSV99678520; called by muse, mutect2, varscan2
- MLXIP | c.2651C>T p.T884M | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs528028662, COSV59836738; called by muse, mutect2, varscan2
- MMRN2 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 23/27 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100922469, COSV64401397; called by muse, mutect2, varscan2
- MMUT | c.544dup p.M182Nfs*29 | Frame Shift Ins (INS) | VAF 54/97 reads (56%) | catalogued as rs746556715; called by mutect2, pindel, varscan2
- MORC2 | c.377C>T p.T126I (on ENST00000397641 / NM_001303256.3; = p.T64I on NM_014941.3) | Missense Mutation (SNP) | VAF 187/269 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755523808, COSV99309373; called by muse, mutect2, varscan2
- MORC2 | c.317C>T p.S106L (on ENST00000397641 / NM_001303256.3; = p.S44L on NM_014941.3) | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53201035; called by muse, mutect2, varscan2
- MPP1 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 458/700 reads (65%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs782624566, COSV65728680; called by muse, mutect2, varscan2
- MTMR7 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 207/296 reads (70%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.481); catalogued as rs773706780, COSV51665581; called by muse, mutect2, varscan2
- MYCBP2 | c.12604G>A p.V4202I (on ENST00000357337; = p.V4240I on NM_015057.5) | Missense Mutation (SNP) | VAF 218/330 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs1208962666, COSV100628986; called by muse, mutect2, varscan2
- MYLK | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 36/40 reads (90%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs150006791, COSV100658398; called by muse, mutect2, varscan2
- MYOM1 | c.3752C>T p.A1251V | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as rs1255173289, COSV99864968; called by muse, mutect2, varscan2
- MYOM2 | c.3157G>A p.D1053N | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as rs373969624, COSV50704558; called by muse, mutect2, varscan2
- NCKIPSD | c.1430C>T p.T477M | Missense Mutation (SNP) | VAF 69/94 reads (73%) | SIFT deleterious (0.02); PolyPhen benign (0.114); catalogued as rs143436723; called by muse, mutect2, varscan2
- NCLN | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1183097829, COSV99859618; called by muse, mutect2, varscan2
- NEFH | c.3049G>A p.A1017T | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs372541633; called by muse, mutect2, varscan2
- NEGR1 | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 43/369 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs372023233; called by muse, mutect2, varscan2
- NOL4L | c.1222C>T p.R408W | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs779165706, COSV100675542; called by muse, mutect2, varscan2
- NOTCH2 | c.6178C>T p.R2060C | Missense Mutation (SNP) | VAF 224/281 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs746551843, CM146466, COSV99862434; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRDE2 | c.3369G>A p.K1123= | Splice Region (SNP) | VAF 176/242 reads (73%) | catalogued as COSV100583206; called by muse, mutect2
- NUP153 | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763590579, COSV100019664; called by muse, mutect2, varscan2
- NXPH4 | c.853A>G p.S285G | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.09); PolyPhen benign (0.121); catalogued as COSV100196932; called by muse, mutect2, varscan2
- OGG1 | c.854C>T p.T285M | Missense Mutation (SNP) | VAF 103/140 reads (74%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs750447639, COSV56537920; called by muse, mutect2, varscan2
- OR51T1 | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 478/657 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs760343102, COSV59024300; called by muse, mutect2, varscan2
- OR52W1 | c.754_755del p.V252Hfs*78 | Frame Shift Del (DEL) | VAF 198/1691 reads (12%) | catalogued as rs1168895823; called by pindel, varscan2
- OTOF | c.5455G>A p.E1819K (on ENST00000272371 / NM_194248.3; = p.E1052K on NM_004802.4) | Missense Mutation (SNP) | VAF 107/153 reads (70%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.855); catalogued as rs538506086, COSV99716276; called by muse, mutect2, varscan2
- P2RX4 | c.929C>T p.T310M | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs566926483, COSV61502320; called by muse, mutect2, varscan2
- P2RY6 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 45/60 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs538929878, COSV100573822; called by muse, mutect2, varscan2
- P4HTM | c.445G>A p.G149S | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as rs778402583, COSV100637504; called by muse, mutect2, varscan2
- PAK5 | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 163/233 reads (70%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs745765163, COSV100781002, COSV62027225; called by muse, mutect2, varscan2
- PCDH1 | c.2345G>A p.R782Q | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0.107); catalogued as rs753094322, COSV99745383; called by muse, mutect2, varscan2
- PCDHA2 | c.1499G>T p.G500V | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as COSV100973430; called by muse, mutect2, varscan2
- PCDHA7 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 49/72 reads (68%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.581); catalogued as rs781874568, COSV65346179; called by muse, mutect2, varscan2
- PCDHA7 | c.1892T>G p.I631S | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV100971194; called by muse, mutect2, varscan2
- PCDHA8 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100970354; called by muse, mutect2, varscan2
- PCDHA9 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 45/75 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.975); catalogued as rs1364235763, COSV65325112; called by muse, mutect2, varscan2
- PCDHB15 | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.014); catalogued as COSV50862524; called by muse, mutect2, varscan2
- PCDHB3 | c.1732C>T p.R578W | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.233); catalogued as rs1554272550; called by muse, varscan2
- PCDHGA11 | c.1439C>T p.P480L | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.031); catalogued as rs775380177, COSV99529952; called by muse, mutect2, varscan2
- PCDHGB2 | c.1970C>T p.T657M | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772642653, COSV53970593; called by muse, mutect2, varscan2
- PCLO | c.12233G>A p.R4078H | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs776696773, COSV100426567; called by muse, mutect2, varscan2
- PCNT | c.8989G>A p.V2997M | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as rs781469305, COSV64034773; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDP1 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772803719, COSV99891837; called by muse, mutect2, varscan2
- PERP | c.513C>A p.C171* | Nonsense Mutation (SNP) | VAF 75/127 reads (59%) | catalogued as COSV101408575; called by muse, mutect2, varscan2
- PEX10 | c.799G>A p.V267I | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs201639783; called by muse, mutect2, varscan2
- PGM3 | c.1486C>T p.R496W | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745488561, COSV52284570; called by muse, mutect2, varscan2
- PHF13 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 30/36 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99275388; called by muse, mutect2, varscan2
- PHF2 | c.2147C>T p.T716M | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.813); catalogued as rs368672670; called by muse, varscan2
- PHLPP1 | c.4486G>A p.D1496N | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV99407161; called by muse, mutect2, varscan2
- PINK1 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 110/143 reads (77%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.88); catalogued as rs747359904, COSV58630510; called by muse, mutect2, varscan2
- PIWIL1 | c.1765C>T p.R589* | Nonsense Mutation (SNP) | VAF 103/223 reads (46%) | catalogued as rs767847661, COSV99805917; called by muse, mutect2, varscan2
- PLEKHH2 | c.2756G>T p.G919V | Missense Mutation (SNP) | VAF 94/137 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99174264; called by muse, mutect2, varscan2
- PLXNB1 | c.2213C>T p.P738L | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV56486388; called by muse, mutect2, varscan2
- POFUT1 | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 80/119 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as COSV65260165; called by muse, mutect2, varscan2
- POGZ | c.2543G>A p.R848Q | Missense Mutation (SNP) | VAF 154/229 reads (67%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.557); catalogued as rs762138684, COSV51851764; called by muse, mutect2, varscan2
- POLE | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as rs1060500853, COSV57692365; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLM | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs746607273, COSV99641608; called by muse, mutect2, varscan2
- POLR2D | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 101/197 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.146); catalogued as COSV99760913; called by muse, mutect2, varscan2
- POMK | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 64/101 reads (63%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs370978230; called by muse, mutect2, varscan2
- PPP1R18 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs780349967, COSV99223514; called by muse, mutect2, varscan2
- PPP2R5D | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 80/115 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100028406; called by muse, mutect2, varscan2
- PRICKLE3 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 92/112 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376861498, COSV100889883; called by muse, mutect2, varscan2
- PRKACG | c.107A>T p.Q36L | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV99597770; called by muse, mutect2
- PRMT7 | c.631G>A p.V211I | Missense Mutation (SNP) | VAF 322/446 reads (72%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs766621192, COSV59833109; called by muse, mutect2, varscan2
- PROKR1 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 38/358 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs752794253, COSV100375695, COSV58137714; called by muse, mutect2
- PROX1 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 53/68 reads (78%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV54775764; called by muse, mutect2, varscan2
- PRSS36 | c.2005C>T p.R669W | Missense Mutation (SNP) | VAF 33/42 reads (79%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs371765050; called by muse, mutect2, varscan2
- PSD | c.2534G>A p.R845Q | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); catalogued as rs1397406971, COSV99192105; called by muse, mutect2, varscan2
- PSMD3 | c.272C>A p.P91Q | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as COSV99227492; called by muse, mutect2, varscan2
- PTPRF | c.5029G>A p.E1677K | Missense Mutation (SNP) | VAF 74/99 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1463828635, COSV100740470; called by muse, mutect2, varscan2
- PTPRN2 | c.1693G>A p.V565M | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.041); catalogued as rs746331581, COSV67064337; called by muse, mutect2, varscan2
- PTPRS | c.70G>A p.V24I | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs200430287, COSV53639724, COSV99508774; called by muse, mutect2, varscan2
- PTPRU | c.2413G>A p.A805T | Missense Mutation (SNP) | VAF 97/141 reads (69%) | SIFT tolerated (0.2); PolyPhen benign (0.081); catalogued as rs1217637863, COSV60530790; called by muse, mutect2, varscan2
- PXDN | c.2734G>A p.A912T | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs770394672, COSV53227060; called by muse, mutect2, varscan2
- QSOX1 | c.1720C>T p.R574W | Missense Mutation (SNP) | VAF 58/71 reads (82%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs371276500, COSV100852793; called by muse, mutect2, varscan2
- RASD2 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 62/84 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1569102268, COSV99332620; called by muse, mutect2, varscan2
- RBM14 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as rs1375178966, COSV59560349; called by muse, mutect2, varscan2
- RBM4 | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 143/186 reads (77%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs766435416, COSV59518011; called by muse, mutect2, varscan2
- RBM45 | c.1258G>A p.E420K (on ENST00000616198 / NM_001365579.1; = p.E418K on NM_152945.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/117 reads (65%) | SIFT tolerated (0.12); PolyPhen benign (0.116); catalogued as COSV53721851; called by muse, mutect2, varscan2
- REEP3 | c.337C>T p.R113* | Nonsense Mutation (SNP) | VAF 62/88 reads (70%) | catalogued as rs769123093, COSV53426468; called by muse, mutect2, varscan2
- RELN | c.7282C>T p.R2428W | Missense Mutation (SNP) | VAF 67/160 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs751431158, COSV58991199; called by muse, mutect2, varscan2
- RESF1 | c.2000G>A p.S667N | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV100440012; called by muse, mutect2, varscan2
- RHNO1 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.178); catalogued as COSV100817002; called by muse, mutect2, varscan2
- RHOH | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 80/105 reads (76%) | SIFT tolerated (1); PolyPhen probably damaging (0.984); catalogued as rs200653414, COSV67805884; called by muse, mutect2, varscan2
- RIMBP2 | c.2917G>A p.D973N | Missense Mutation (SNP) | VAF 685/1498 reads (46%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs765553561, COSV99898084; called by muse, mutect2, varscan2
- RIMBP2 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 56/116 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as rs1232633444, COSV55466326, COSV99900903; called by muse, mutect2, varscan2
- RMND5A | c.1009C>A p.P337T | Missense Mutation (SNP) | VAF 56/98 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99373539; called by muse, mutect2, varscan2
- RNF32 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 65/129 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as rs777015389, COSV100311143, COSV100311337; called by muse, mutect2, varscan2
- ROCK1 | c.2888C>G p.T963R | Missense Mutation (SNP) | VAF 60/210 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV101296209; called by muse, mutect2, varscan2
- ROS1 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 236/335 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as rs145609658, COSV63861203; called by muse, mutect2, varscan2
- RPL18A | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as rs369237728; called by muse, mutect2, varscan2
- RTL5 | c.1636C>T p.R546C | Missense Mutation (SNP) | VAF 36/43 reads (84%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs1326767228, COSV101029830; called by muse, mutect2, varscan2
- RUFY2 | c.1021C>T p.R341* | Nonsense Mutation (SNP) | VAF 77/120 reads (64%) | catalogued as COSV66252199; called by muse, mutect2, varscan2
- SCN5A | c.1702C>T p.R568C | Missense Mutation (SNP) | VAF 39/55 reads (71%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as rs45600438; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 24/38 reads (63%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEMA4G | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs372839640, COSV99271798; called by muse, mutect2, varscan2
- SERPINA5 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.084); catalogued as rs138759608; called by muse, mutect2
- SH2B2 | c.1676G>A p.R559Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.852); catalogued as rs1554558189, COSV100159204; called by muse, mutect2, varscan2
- SH2D3A | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs146265436, COSV55585064; called by muse, mutect2, varscan2
- SH3BP5 | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 107/142 reads (75%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs763097509, COSV99508000, COSV99508560; called by muse, mutect2, varscan2
- SHPRH | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 94/129 reads (73%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as rs750369986, COSV51604239, COSV99261131; called by muse, mutect2, varscan2
- SLC13A3 | c.1174_1176del p.F392del | In Frame Del (DEL) | VAF 144/312 reads (46%) | catalogued as rs748317513; called by pindel, varscan2
- SLC15A1 | c.70T>A p.F24I | Missense Mutation (SNP) | VAF 107/136 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100918173; called by muse, mutect2, varscan2
- SLC25A39 | c.976C>T p.R326W (on ENST00000377095 / NM_001143780.3; = p.R318W on NM_016016.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs778758238, COSV56587155; called by muse, mutect2, varscan2
- SLC26A6 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 41/50 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753418877, COSV50964797; called by muse, mutect2, varscan2
- SLC41A1 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 37/49 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1362661211, COSV100900309; called by muse, mutect2, varscan2
- SLC41A3 | c.961G>A p.V321I | Missense Mutation (SNP) | VAF 267/402 reads (66%) | SIFT tolerated (0.27); PolyPhen benign (0.088); catalogued as rs138712564; called by muse, mutect2, varscan2
- SLC8A3 | c.1661G>A p.R554Q | Missense Mutation (SNP) | VAF 86/132 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs982655652, COSV63521042, COSV63523482; called by muse, mutect2, varscan2
- SLIT3 | c.1717C>T p.R573* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100265025; called by muse, mutect2
- SMAD1 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 98/145 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57471604; called by muse, mutect2, varscan2
- SMAD4 | c.410T>C p.V137A | Missense Mutation (SNP) | VAF 88/161 reads (55%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV100747430; called by muse, mutect2, varscan2
- SMARCA1 | c.1829G>A p.R610H | Missense Mutation (SNP) | VAF 128/149 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64414286; called by muse, mutect2, varscan2
- SMTN | c.2017G>A p.V673I | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs771689259, COSV60784003; called by muse, mutect2, varscan2
- SNAP25 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 256/376 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV54775129; called by muse, mutect2, varscan2
- SND1 | c.1336G>A p.G446R | Missense Mutation (SNP) | VAF 91/318 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100689554; called by muse, mutect2, varscan2
- SNX13 | c.921A>C p.R307S | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV101296770; called by muse, mutect2, varscan2
- SNX25 | c.884C>T p.T295M | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs765732691, COSV99252235; called by muse, mutect2, varscan2
- SNX4 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 152/193 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745747650, COSV99304601; called by muse, mutect2, varscan2
- SOGA1 | c.1424G>A p.R475Q | Missense Mutation (SNP) | VAF 27/32 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99412545, COSV99415783; called by muse, mutect2, varscan2
- SORCS2 | c.2777C>T p.T926M | Missense Mutation (SNP) | VAF 74/112 reads (66%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.832); catalogued as rs373844040; called by muse, mutect2, varscan2
- SP140 | c.2015del p.K672Rfs*4 | Frame Shift Del (DEL) | VAF 34/48 reads (71%) | catalogued as rs746109620; called by mutect2, varscan2
- SPATA2 | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 48/71 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs36105169; called by muse, mutect2, varscan2
- SPHKAP | c.4390A>G p.N1464D | Missense Mutation (SNP) | VAF 62/212 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.053); catalogued as rs751958613, COSV100763613; called by muse, mutect2, varscan2
- SPRYD4 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV100358171; called by muse, mutect2, varscan2
- SRL | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 179/226 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs371482288; called by muse, mutect2, varscan2
- SRRM4 | c.1544G>A p.R515H | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57414885; called by muse, mutect2
- SRSF5 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 50/65 reads (77%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.602); catalogued as rs763081161, COSV53681614; called by muse, mutect2, varscan2
- STK35 | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 78/112 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99852557; called by muse, mutect2, varscan2
- STOML3 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 124/174 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs747314352, COSV65509822; called by muse, varscan2
- STOX2 | c.1285G>A p.V429M | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs779021205, COSV100408260; called by muse, mutect2, varscan2
- STYXL2 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 50/75 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs748897144, COSV54801697, COSV99608439; called by muse, mutect2, varscan2
- SVIL | c.5434G>A p.V1812I (on ENST00000355867 / NM_021738.3; = p.V1386I on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/58 reads (76%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as rs762726751, COSV100880799; called by muse, mutect2, varscan2
- TAF1L | c.3719G>A p.R1240Q | Missense Mutation (SNP) | VAF 117/168 reads (70%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as rs539586559, COSV54259824; called by muse, mutect2, varscan2
- TAGAP | c.1171C>T p.R391W | Missense Mutation (SNP) | VAF 44/65 reads (68%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV57852544, COSV57853506; called by muse, mutect2, varscan2
- TAOK3 | c.1970G>A p.R657Q | Missense Mutation (SNP) | VAF 53/211 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs753899938, COSV101183383; called by muse, mutect2, varscan2
- TBC1D12 | c.4G>A p.V2M | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.01); catalogued as rs765254148, COSV99831095; called by muse, mutect2, varscan2
- TBXT | c.1231G>A p.V411M | Missense Mutation (SNP) | VAF 60/73 reads (82%) | SIFT tolerated (0.1); PolyPhen benign (0.115); catalogued as rs771064715, COSV51620224; called by muse, mutect2, varscan2
- TFCP2L1 | c.1244T>C p.I415T | Missense Mutation (SNP) | VAF 148/181 reads (82%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1167932902, COSV55292175; called by muse, mutect2, varscan2
- THSD7A | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1562427143, COSV101448959, COSV70264824; called by muse, mutect2, varscan2
- TM9SF4 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 87/108 reads (81%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.916); catalogued as rs577831447, COSV99453736; called by muse, mutect2, varscan2
- TMCC2 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs778462308, COSV100787917; called by muse, mutect2, varscan2
- TMEM135 | c.934A>T p.K312* | Nonsense Mutation (SNP) | VAF 60/82 reads (73%) | catalogued as COSV100449253; called by muse, mutect2, varscan2
- TMEM175 | c.1363G>A p.V455M | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs762011503, COSV99297456; called by muse, mutect2, varscan2
- TNKS2 | c.3298C>T p.R1100W | Missense Mutation (SNP) | VAF 143/184 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768080166, COSV100860965; called by muse, mutect2, varscan2
- TNS3 | c.2929G>A p.G977S | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1425351177, COSV100234529; called by muse, mutect2, varscan2
- TPRN | c.1634G>A p.R545H | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150227451; called by muse, mutect2
- TRAF2 | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as rs767258846, COSV56040237; called by muse, mutect2, varscan2
- TRIM9 | c.1871G>A p.R624Q | Missense Mutation (SNP) | VAF 320/450 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759860492, COSV100030297; called by muse, mutect2, varscan2
- TRIO | c.2179G>A p.V727M | Missense Mutation (SNP) | VAF 227/661 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs748582661, COSV60092892; called by muse, mutect2, varscan2
- TRPC5 | c.1475G>A p.R492H | Missense Mutation (SNP) | VAF 282/336 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1010020042, COSV53291712; called by muse, mutect2, varscan2
- TRPC7 | c.256G>A p.V86M | Missense Mutation (SNP) | VAF 40/232 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1274493309, COSV61452394; called by muse, mutect2, varscan2
- TRPM6 | c.2138C>T p.S713L | Missense Mutation (SNP) | VAF 141/201 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs971269569, COSV62504728; called by muse, mutect2, varscan2
- TRRAP | c.4473C>T p.N1491= | Splice Region (SNP) | VAF 25/104 reads (24%) | catalogued as rs1433592568, COSV62852337; called by muse, mutect2, varscan2
- TRRAP | c.9481G>A p.D3161N (on ENST00000359863 / NM_001244580.1; = p.D3132N on NM_003496.3) | Missense Mutation (SNP) | VAF 68/204 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV62855909; called by muse, mutect2, varscan2
- TSHZ2 | c.2454del p.M819* | Frame Shift Del (DEL) | VAF 74/112 reads (66%) | catalogued as COSV100295175, COSV100295449; called by mutect2, varscan2
- TSSK6 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT tolerated (0.26); PolyPhen benign (0.086); catalogued as rs1027241107, COSV99388859; called by muse, mutect2, varscan2
- TTC17 | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 110/145 reads (76%) | catalogued as COSV50025346, COSV99236078; called by muse, mutect2, varscan2
- TTN | c.11174C>G p.A3725G (on ENST00000591111; = p.A3679G on NM_003319.4) | Missense Mutation (SNP) | VAF 205/280 reads (73%) | catalogued as COSV100590923; called by muse, mutect2, varscan2
- TUBA3C | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 166/220 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.103); catalogued as rs757305289, COSV67140272; called by muse, mutect2, varscan2
- TUBGCP5 | c.2306G>A p.R769H | Missense Mutation (SNP) | VAF 39/52 reads (75%) | SIFT tolerated (0.52); PolyPhen benign (0.164); catalogued as rs755058797; called by muse, mutect2, varscan2
- UGT2B15 | c.1432C>T p.R478* | Nonsense Mutation (SNP) | VAF 352/552 reads (64%) | catalogued as rs774308500, COSV57734038; called by muse, mutect2, varscan2
- ULK4 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT tolerated (0.54); PolyPhen benign (0.11); catalogued as rs773719911, COSV57225750; called by muse, mutect2, varscan2
- UNC79 | c.2849C>T p.P950L (on ENST00000393151 / NM_001346218.2; = p.P773L on NM_020818.5) | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99825363; called by muse, mutect2, varscan2
- UPK1B | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 98/142 reads (69%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.992); catalogued as rs769046663, COSV99953452; called by muse, mutect2, varscan2
- USP11 | c.1783C>T p.R595W (on ENST00000218348; = p.R552W on NM_001371072.1) | Missense Mutation (SNP) | VAF 81/99 reads (82%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99510595; called by muse, mutect2, varscan2
- USP5 | c.146C>T p.T49M | Missense Mutation (SNP) | VAF 93/199 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs149569083; called by muse, mutect2, varscan2
- USP5 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1247525332, COSV99978071; called by muse, mutect2, varscan2
- USP9X | c.1475G>A p.R492H | Missense Mutation (SNP) | VAF 73/249 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61078003; called by muse, mutect2, varscan2
- USP9X | c.5224G>A p.V1742I | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT tolerated (0.17); PolyPhen benign (0.343); catalogued as rs1277274504, COSV100198365; called by muse, mutect2, varscan2
- VAV2 | c.1057C>T p.R353W (on ENST00000371850 / NM_001134398.2; = p.R348W on NM_003371.4) | Missense Mutation (SNP) | VAF 52/81 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs200570910, COSV64083371; called by muse, mutect2, varscan2
- VAV2 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs762083852, COSV100895489; called by muse, mutect2, varscan2
- VIPR2 | c.760G>A p.V254I | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.042); catalogued as rs145308657; called by muse, mutect2, varscan2
- VWCE | c.2470C>T p.H824Y | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.062); catalogued as COSV100075495; called by muse, mutect2, varscan2
- WASHC4 | c.2150G>A p.R717Q | Missense Mutation (SNP) | VAF 60/136 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as rs200606954, COSV100161969; called by muse, mutect2, varscan2
- WASHC5 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 134/180 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs778430741, COSV59194432; called by muse, mutect2, varscan2
- WDR36 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs773683578, COSV72411334; called by muse, mutect2, varscan2
- WDR41 | c.437A>T p.D146V | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as rs1463602184, COSV99689019; called by muse, mutect2, varscan2
- WDR91 | c.1949C>T p.T650M | Missense Mutation (SNP) | VAF 62/206 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs763076031, COSV60371978; called by muse, mutect2, varscan2
- WNK3 | c.4694G>A p.R1565H | Missense Mutation (SNP) | VAF 69/89 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1192392222, COSV63612715; called by muse, mutect2, varscan2
- WNT3 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 52/65 reads (80%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV56644417; called by muse, mutect2, varscan2
- WRAP53 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.534); catalogued as rs776212278, COSV99872574; called by muse, mutect2, varscan2
- YPEL1 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 60/90 reads (67%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as COSV58606770; called by muse, mutect2, varscan2
- ZAN | c.4753G>A p.A1585T | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT tolerated (0.67); PolyPhen benign (0.127); catalogued as rs751470697, COSV100769007; called by muse, mutect2, varscan2
- ZAN | c.6055G>A p.A2019T | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as rs1290287671, COSV100769008; called by muse, mutect2, varscan2
- ZC3H7B | c.954dup p.A319Rfs*58 | Frame Shift Ins (INS) | VAF 5/40 reads (13%) | catalogued as rs768896328; called by pindel, varscan2
- ZC3HAV1 | c.435del p.F145Lfs*49 | Frame Shift Del (DEL) | VAF 48/130 reads (37%) | catalogued as rs1363033923; called by mutect2, pindel, varscan2
- ZFYVE1 | c.1771G>A p.A591T | Missense Mutation (SNP) | VAF 148/186 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760423155, COSV100606464; called by muse, mutect2, varscan2
- ZFYVE26 | c.3997A>G p.S1333G | Missense Mutation (SNP) | VAF 89/138 reads (64%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100720015; called by muse, mutect2, varscan2
- ZNF226 | c.37G>A p.V13M | Missense Mutation (SNP) | VAF 207/306 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as rs752607335, COSV100334989; called by muse, mutect2, varscan2
- ZNF281 | c.2474C>T p.T825M | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1469386225; called by muse, mutect2, varscan2
- ZNF292 | c.7285C>T p.R2429W | Missense Mutation (SNP) | VAF 40/61 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs1379680822, COSV60544735; called by muse, mutect2, varscan2
- ZNF48 | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs567018085, COSV100198001; called by muse, mutect2, varscan2
- ZNF551 | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 93/128 reads (73%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as rs201300581, COSV99989679; called by muse, mutect2, varscan2
- ZNF71 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 49/71 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs747778809, COSV60147768; called by muse, mutect2, varscan2
- ZWINT | c.687G>T p.E229D | Missense Mutation (SNP) | VAF 50/57 reads (88%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV59184996; called by muse, mutect2, varscan2
- AGER | c.798_799del p.P267Sfs*23 | Frame Shift Del (DEL) | VAF 102/234 reads (44%) | called by pindel, varscan2
- ANO5 | c.284_285del p.E95Vfs*10 | Frame Shift Del (DEL) | VAF 80/136 reads (59%) | called by pindel, varscan2
- AQP10 | c.267G>T p.M89I | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.437); called by muse, mutect2
- ASB5 | c.77_81del p.C26* | Frame Shift Del (DEL) | VAF 38/54 reads (70%) | called by mutect2, pindel, varscan2
- ATL1 | c.1355_1358del p.F452* | Frame Shift Del (DEL) | VAF 181/267 reads (68%) | called by mutect2, pindel, varscan2
- BTBD1 | c.1290+2_1290+5del p.X430_splice | Splice Site (DEL) | VAF 72/109 reads (66%) | called by mutect2, pindel, varscan2
- C1GALT1C1 | c.482dup p.D162Gfs*18 | Frame Shift Ins (INS) | VAF 19/39 reads (49%) | called by mutect2, pindel, varscan2
- CAV2 | c.220C>T p.H74Y | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.217); called by muse, mutect2
- CEP57 | c.1069_1071del p.N357del | In Frame Del (DEL) | VAF 85/116 reads (73%) | called by mutect2, pindel, varscan2
- DCAF4L1 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.129); called by muse, mutect2
- DCLRE1A | c.1008_1010del p.E336del | In Frame Del (DEL) | VAF 57/82 reads (70%) | called by pindel, varscan2
- HECW2 | c.2763dup p.V922Rfs*16 | Frame Shift Ins (INS) | VAF 148/352 reads (42%) | called by pindel, varscan2
- HIP1 | c.2158+2_2158+3del p.X720_splice | Splice Site (DEL) | VAF 8/24 reads (33%) | called by pindel, varscan2
- KATNIP | c.2272_2274del p.S758del | In Frame Del (DEL) | VAF 249/370 reads (67%) | called by mutect2, pindel, varscan2
- KBTBD3 | c.678C>A p.N226K | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, mutect2
- KIR2DL4 | c.1141T>A p.S381T (on ENST00000396284; = p.S307T on NM_001080770.2) | Missense Mutation (SNP) | VAF 112/570 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LRRN2 | c.1292del p.P431Qfs*5 | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | called by mutect2, pindel, varscan2
- MRC1 | c.1562C>T p.T521M | Missense Mutation (SNP) | VAF 286/388 reads (74%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- MRPS31 | c.1151dup p.D385Gfs*7 | Frame Shift Ins (INS) | VAF 6/8 reads (75%) | called by mutect2, varscan2
- PDCD4 | c.67_70del p.L23Ffs*13 | Frame Shift Del (DEL) | VAF 24/39 reads (62%) | called by mutect2, pindel, varscan2
- PDXDC1 | c.686_687del p.I229Rfs*32 | Frame Shift Del (DEL) | VAF 52/225 reads (23%) | called by pindel, varscan2
- PLEKHA6 | c.785del p.G262Vfs*54 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | called by mutect2, pindel, varscan2
- PRAMEF19 | c.637T>C p.W213R | Missense Mutation (SNP) | VAF 248/293 reads (85%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRPF40B | c.1178_1180del p.D393del (on ENST00000380281; = p.D387del on NM_012272.3) | In Frame Del (DEL) | VAF 54/208 reads (26%) | called by pindel, varscan2
- PSD | c.819_820del p.V275Gfs*25 | Frame Shift Del (DEL) | VAF 13/22 reads (59%) | called by mutect2, pindel, varscan2
- PTEN | c.492+3_492+4del | Splice Region (DEL) | VAF 55/110 reads (50%) | called by mutect2, pindel, varscan2
- RFX3 | c.2041_2044del p.D681Kfs*18 | Frame Shift Del (DEL) | VAF 34/56 reads (61%) | called by mutect2, pindel, varscan2
- RRP15 | c.53del p.K18Rfs*7 | Frame Shift Del (DEL) | VAF 67/113 reads (59%) | called by mutect2, pindel, varscan2
- SEL1L | c.1074_1076del p.E358del | In Frame Del (DEL) | VAF 59/92 reads (64%) | called by pindel, varscan2
- SPDEF | c.823_825del p.E275del | In Frame Del (DEL) | VAF 53/72 reads (74%) | called by mutect2, pindel, varscan2
- SPIC | c.437dup p.N146Kfs*50 | Frame Shift Ins (INS) | VAF 41/100 reads (41%) | called by mutect2, pindel, varscan2
- TMEM95 | c.300del p.R101Gfs*61 (on ENST00000576060 / NM_001320436.2; = p.R101Gfs*69 on NM_198154.3) | Frame Shift Del (DEL) | VAF 58/108 reads (54%) | called by mutect2, pindel, varscan2
- TRAV7 | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TTN | c.62186_62187del p.S20729Cfs*11 (on ENST00000591111; = p.S13305Cfs*11 on NM_003319.4) | Frame Shift Del (DEL) | VAF 34/74 reads (46%) | called by pindel, varscan2
- UGCG | c.700G>T p.A234S | Missense Mutation (SNP) | VAF 9/177 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); called by muse, mutect2
- UROD | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2
- VCAN | c.8279_8281del p.S2760del | In Frame Del (DEL) | VAF 40/72 reads (56%) | called by pindel, varscan2
- WIPI2 | c.497_500del p.I166Tfs*26 | Frame Shift Del (DEL) | VAF 136/190 reads (72%) | called by pindel, varscan2
- XKR9 | c.98dup p.H34Pfs*2 | Frame Shift Ins (INS) | VAF 174/329 reads (53%) | called by mutect2, pindel, varscan2
- ZMYM6 | c.3957dup p.L1320Ifs*26 | Frame Shift Ins (INS) | VAF 6/60 reads (10%) | called by pindel, varscan2
- ZNF683 | c.732del p.H245Tfs*56 | Frame Shift Del (DEL) | VAF 9/91 reads (10%) | called by mutect2, pindel, varscan2
- ABCB10 | c.624C>T p.S208= | Silent (SNP) | VAF 18/206 reads (9%) | catalogued as rs752211152, COSV100747830; called by muse, mutect2
- ABCG5 | c.1311C>T p.N437= | Silent (SNP) | VAF 30/46 reads (65%) | catalogued as rs575266356, CM012721, COSV53213025; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AC068580.4 | c.345C>T p.I115= | Silent (SNP) | VAF 9/11 reads (82%) | catalogued as rs200875086, COSV99362193; ClinVar: likely benign; called by muse, mutect2, varscan2
- ACSM4 | c.960T>C p.P320= | Silent (SNP) | VAF 80/271 reads (30%) | catalogued as COSV101256967; called by muse, mutect2, varscan2
- ADPRS | c.612C>T p.G204= | Silent (SNP) | VAF 34/44 reads (77%) | catalogued as rs201313351, COSV99255353; called by muse, mutect2, varscan2
- AEBP1 | c.2886G>A p.P962= | Silent (SNP) | VAF 33/61 reads (54%) | catalogued as COSV56257306; called by muse, mutect2, varscan2
- AIPL1 | c.93C>T p.S31= | Silent (SNP) | VAF 25/31 reads (81%) | catalogued as COSV100005916; called by muse, mutect2, varscan2
- ALDH3A2 | c.513G>A p.T171= | Silent (SNP) | VAF 25/32 reads (78%) | catalogued as rs370609228; called by muse, mutect2, varscan2
- AP2A2 | c.1188C>T p.C396= | Silent (SNP) | VAF 33/43 reads (77%) | catalogued as rs759551186, COSV100172392; called by muse, mutect2, varscan2
- ARFGAP1 | c.567G>A p.T189= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as rs755280290, COSV100796606; called by muse, mutect2, varscan2
- ARSK | c.432G>A p.A144= | Silent (SNP) | VAF 174/556 reads (31%) | catalogued as rs368652470, COSV66169917; called by muse, mutect2, varscan2
- ASIC1 | c.1515C>T p.A505= | Silent (SNP) | VAF 27/54 reads (50%) | catalogued as rs776738327, COSV99947875; called by muse, mutect2, varscan2
- ASXL2 | c.1890G>A p.P630= | Silent (SNP) | VAF 56/91 reads (62%) | catalogued as rs754898134, COSV99709996; called by muse, mutect2, varscan2
- ATP4B | c.639G>A p.P213= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as rs750469325, COSV100089595; called by muse, mutect2, varscan2
- AVPR1B | c.108G>A p.V36= | Silent (SNP) | VAF 67/97 reads (69%) | catalogued as rs1474345806, COSV100899290; called by muse, mutect2, varscan2
- BNIP3 | c.639G>A p.T213= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs759648763, COSV100893129; called by mutect2, varscan2
- BSN | c.9492C>T p.I3164= | Silent (SNP) | VAF 24/31 reads (77%) | catalogued as rs781242663, COSV99607029; called by muse, mutect2, varscan2
- CABLES2 | c.642G>A p.P214= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as rs201432490, COSV99652901; called by mutect2, varscan2
- CASQ2 | c.924G>A p.P308= | Silent (SNP) | VAF 144/178 reads (81%) | catalogued as rs761798969, COSV54767979; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC27 | c.336C>T p.A112= | Silent (SNP) | VAF 23/110 reads (21%) | catalogued as rs757029536, COSV99621963; called by muse, varscan2
- CCT8L2 | c.1386C>T p.D462= | Silent (SNP) | VAF 93/279 reads (33%) | catalogued as rs370876356; called by muse, mutect2, varscan2
- CD248 | c.1275G>A p.P425= | Silent (SNP) | VAF 20/23 reads (87%) | catalogued as rs761013213, COSV100256433; called by muse, mutect2, varscan2
- CD53 | c.357C>T p.T119= | Silent (SNP) | VAF 462/605 reads (76%) | catalogued as rs201211085, COSV54760880, COSV99602038; called by muse, mutect2, varscan2
- CEMIP2 | c.1962G>A p.V654= | Silent (SNP) | VAF 16/297 reads (5%) | catalogued as rs1279274636; called by muse, mutect2
- CLDN4 | c.417G>A p.T139= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs202009827, COSV99936280; called by muse, mutect2, varscan2
- CLIP2 | c.1746C>T p.R582= | Silent (SNP) | VAF 16/25 reads (64%) | catalogued as rs782382338, COSV56274513; called by muse, mutect2, varscan2
- CNTN5 | c.855G>A p.T285= | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as rs1448252108, COSV54358544; called by muse, mutect2, varscan2
- CNTNAP2 | c.1032C>T p.G344= | Silent (SNP) | VAF 60/176 reads (34%) | catalogued as rs142122012, COSV62145397; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- CNTNAP2 | c.2667G>A p.R889= | Silent (SNP) | VAF 82/381 reads (22%) | catalogued as COSV100661899; called by muse, mutect2, varscan2
- CRACR2B | c.201G>A p.Q67= | Silent (SNP) | VAF 12/16 reads (75%) | catalogued as COSV100351910; called by muse, mutect2
- CREB3L1 | c.1236C>T p.D412= | Silent (SNP) | VAF 19/26 reads (73%) | catalogued as rs755341231, COSV55832875; called by muse, mutect2, varscan2
- CREBBP | c.5010C>T p.L1670= | Silent (SNP) | VAF 11/17 reads (65%) | catalogued as rs62037853, COSV99268275; called by muse, mutect2, varscan2
- CTSD | c.1137C>T p.S379= | Silent (SNP) | VAF 9/12 reads (75%) | catalogued as rs141981301; ClinVar: likely benign; called by muse, mutect2, varscan2
- DDX23 | c.1893C>T p.S631= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as rs370379176; called by muse, mutect2, varscan2
- DLG5 | c.4617C>T p.D1539= | Silent (SNP) | VAF 12/174 reads (7%) | catalogued as rs376551752; called by muse, mutect2
- DNAH1 | c.5736C>T p.Y1912= | Silent (SNP) | VAF 85/102 reads (83%) | catalogued as rs753771532, COSV101324410; called by muse, mutect2, varscan2
- EFCAB6 | c.4128C>T p.N1376= | Silent (SNP) | VAF 110/194 reads (57%) | catalogued as rs374422528; called by muse, mutect2, varscan2
- EHBP1L1 | c.2430G>A p.A810= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs371915123, COSV58574958; called by muse, mutect2, varscan2
- EOMES | c.1476C>T p.G492= | Silent (SNP) | VAF 56/80 reads (70%) | catalogued as rs62253095, COSV55412912; called by muse, mutect2, varscan2
- EP400 | c.3024C>T p.A1008= | Silent (SNP) | VAF 103/203 reads (51%) | catalogued as rs752148703, COSV100200176; called by muse, mutect2, varscan2
- ERCC3 | c.2304G>A p.A768= | Silent (SNP) | VAF 90/258 reads (35%) | catalogued as rs1354994770, COSV99572985; called by muse, varscan2
- ETFB | c.381C>T p.I127= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as rs149238320; called by muse, varscan2
- EXOC1 | c.555G>A p.A185= | Silent (SNP) | VAF 46/64 reads (72%) | catalogued as rs146961843, COSV100637911; called by muse, mutect2, varscan2
- EXOSC9 | c.618G>A p.L206= | Silent (SNP) | VAF 17/171 reads (10%) | catalogued as COSV99696678; called by muse, mutect2
- FARP1 | c.693G>A p.P231= | Silent (SNP) | VAF 163/179 reads (91%) | catalogued as rs1160916708, COSV100129414; called by muse, mutect2, varscan2
- FBXW8 | c.306G>A p.E102= (on ENST00000309909; = p.E140= on NM_012174.1) | Silent (SNP) | VAF 136/458 reads (30%) | catalogued as COSV99997383; called by muse, mutect2, varscan2
- FFAR2 | c.495C>T p.Y165= | Silent (SNP) | VAF 149/221 reads (67%) | catalogued as rs756254906, COSV55833310; called by muse, mutect2, varscan2
- FILIP1L | c.480G>A p.Q160= | Silent (SNP) | VAF 10/208 reads (5%) | called by muse, mutect2
- FLNC | c.5961C>T p.N1987= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs747515045, COSV57960989; called by muse, mutect2, varscan2
- FOSL2 | c.600G>A p.S200= | Silent (SNP) | VAF 24/35 reads (69%) | catalogued as rs762345143, COSV53103515, COSV99268173; called by muse, mutect2, varscan2
- FRMPD3 | c.369C>T p.I123= | Silent (SNP) | VAF 970/1161 reads (84%) | catalogued as rs1274598114, COSV99345445; called by muse, mutect2, varscan2
- FST | c.456G>A p.E152= | Silent (SNP) | VAF 11/108 reads (10%) | catalogued as rs974025762, COSV99886978; called by muse, mutect2, varscan2
- FYB1 | c.588C>T p.P196= | Silent (SNP) | VAF 92/210 reads (44%) | catalogued as rs200342357, COSV100684656; called by mutect2, varscan2
- GABRR1 | c.1011C>T p.R337= | Silent (SNP) | VAF 461/634 reads (73%) | catalogued as rs185458142, COSV65619626, COSV65620358; called by muse, mutect2, varscan2
- GALM | c.462C>T p.G154= | Silent (SNP) | VAF 143/232 reads (62%) | catalogued as rs369936446; called by muse, mutect2, varscan2
- GCNT3 | c.210T>C p.C70= | Silent (SNP) | VAF 122/195 reads (63%) | catalogued as COSV101251714; called by muse, mutect2, varscan2
- GDF2 | c.711C>T p.C237= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs146775536; ClinVar: likely benign; called by muse, mutect2, varscan2
- GLI2 | c.1383G>A p.T461= (on ENST00000361492 / NM_001374353.1; = p.T478= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 91/129 reads (71%) | catalogued as rs768606373, COSV100082154; ClinVar: benign; called by muse, mutect2, varscan2
- GLI3 | c.3342C>T p.S1114= | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as COSV101229685; called by muse, mutect2, varscan2
- GMIP | c.1524C>T p.C508= | Silent (SNP) | VAF 24/31 reads (77%) | catalogued as rs758393068, COSV52554139; called by muse, mutect2, varscan2
- GNPTAB | c.801G>A p.A267= | Silent (SNP) | VAF 31/58 reads (53%) | catalogued as rs764029931, COSV54778814; called by muse, mutect2, varscan2
- GPRC5B | c.528C>T p.I176= | Silent (SNP) | VAF 50/73 reads (68%) | catalogued as rs761857600, COSV100314866; called by muse, mutect2, varscan2
- GRIN2A | c.1161C>T p.H387= | Silent (SNP) | VAF 213/296 reads (72%) | catalogued as rs367543146, COSV58038088; ClinVar: not provided; called by muse, mutect2, varscan2
- HAUS8 | c.1125G>A p.S375= | Silent (SNP) | VAF 42/53 reads (79%) | catalogued as rs1488584685, COSV99505078; called by muse, mutect2, varscan2
- HIF3A | c.1158C>T p.P386= (on ENST00000377670 / NM_152795.4; = p.P317= on NM_022462.4) | Silent (SNP) | VAF 18/108 reads (17%) | catalogued as rs1270894674, COSV52206024; called by muse, mutect2, varscan2
- HTR7 | c.855C>T p.S285= | Silent (SNP) | VAF 50/64 reads (78%) | catalogued as rs756950797, COSV99518717; called by muse, mutect2, varscan2
- IDH2 | c.1260C>T p.H420= | Silent (SNP) | VAF 158/217 reads (73%) | catalogued as rs139616710; called by muse, mutect2, varscan2
- IGKV2D-24 | c.186G>A p.Q62= | Silent (SNP) | VAF 35/320 reads (11%) | catalogued as rs768603784; called by muse, mutect2, varscan2
- IL5RA | c.648C>T p.N216= | Silent (SNP) | VAF 45/65 reads (69%) | catalogued as rs185027967, COSV56523146, COSV99842589; called by muse, mutect2, varscan2
- ILKAP | c.660G>A p.T220= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs150186666, COSV54517839; called by muse, mutect2, varscan2
- IMPDH1 | c.1524C>T p.Y508= (on ENST00000470772 / NM_001142573.2; = p.Y594= on NM_000883.4) | Silent (SNP) | VAF 36/89 reads (40%) | catalogued as rs368622318, COSV58316753; called by muse, mutect2, varscan2
- INPP5K | c.849C>T p.P283= | Silent (SNP) | VAF 59/71 reads (83%) | catalogued as rs748453410, COSV100233576; called by muse, mutect2, varscan2
- IPO13 | c.825C>T p.Y275= | Silent (SNP) | VAF 48/62 reads (77%) | catalogued as rs1216097064, COSV64894689; called by muse, mutect2, varscan2
- ISLR2 | c.63G>A p.P21= | Silent (SNP) | VAF 83/116 reads (72%) | catalogued as COSV100679339; called by muse, mutect2, varscan2
- KCNMA1 | c.468C>T p.V156= | Silent (SNP) | VAF 91/126 reads (72%) | catalogued as rs140636629; called by muse, mutect2, varscan2
- KCNRG | c.618C>T p.N206= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs777399450, COSV57250223; called by muse, mutect2, varscan2
- KCNS1 | c.1002C>T p.F334= | Silent (SNP) | VAF 19/23 reads (83%) | catalogued as rs1309580953, COSV100066971; called by muse, mutect2, varscan2
- KDM5D | c.1275C>T p.D425= | Silent (SNP) | VAF 231/266 reads (87%) | catalogued as COSV100522128; called by muse, mutect2, varscan2
- KIF13B | c.1989C>T p.S663= | Silent (SNP) | VAF 31/60 reads (52%) | catalogued as rs776506488, COSV101580505; called by muse, mutect2, varscan2
- KIF1B | c.1002G>A p.A334= (on ENST00000377086 / NM_001365952.1; = p.A328= on NM_015074.3) | Silent (SNP) | VAF 62/78 reads (79%) | catalogued as rs771891729, COSV55804834, COSV99822264; called by muse, mutect2, varscan2
- KIF9 | c.1686G>A p.P562= | Silent (SNP) | VAF 40/92 reads (43%) | catalogued as rs145806032; called by muse, mutect2, varscan2
- KSR2 | c.2163C>T p.N721= | Silent (SNP) | VAF 34/138 reads (25%) | catalogued as rs764593853, COSV56674958; called by muse, varscan2
- L3MBTL2 | c.285C>T p.I95= | Silent (SNP) | VAF 91/116 reads (78%) | catalogued as rs755717884, COSV99345591; called by muse, mutect2, varscan2
- LAMC3 | c.3648G>A p.A1216= | Silent (SNP) | VAF 34/74 reads (46%) | catalogued as rs754510883, COSV100735869; called by muse, mutect2, varscan2
- LAT | c.462C>T p.D154= | Silent (SNP) | VAF 16/23 reads (70%) | catalogued as rs535156699, COSV57956659; called by muse, mutect2
- LGALS9 | c.375C>T p.R125= | Silent (SNP) | VAF 107/183 reads (58%) | catalogued as rs754615858, COSV56347921; called by muse, mutect2, varscan2
- LMO7 | c.1908A>T p.G636= (on ENST00000357063; = p.G366= on NM_015842.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs753994039, COSV100412278; called by muse, mutect2, varscan2
- LRRC37A2 | c.4347C>T p.N1449= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as rs1202058469, COSV100238579; called by mutect2, varscan2
- MAGEA11 | c.525T>C p.P175= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV100290350; called by muse, mutect2, varscan2
- MAP1S | c.2250G>A p.A750= | Silent (SNP) | VAF 11/15 reads (73%) | catalogued as rs758396147, COSV60724068; called by muse, mutect2, varscan2
- MASP2 | c.1077C>T p.P359= | Silent (SNP) | VAF 24/30 reads (80%) | catalogued as rs146514683; called by muse, mutect2, varscan2
- MFNG | c.453G>A p.A151= | Silent (SNP) | VAF 75/97 reads (77%) | catalogued as rs771342884, COSV100812832; called by muse, mutect2, varscan2
- MFSD2A | c.1272C>T p.D424= (on ENST00000372809 / NM_001136493.3; = p.D411= on NM_032793.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 113/145 reads (78%) | catalogued as rs774969723, COSV65685520; called by muse, mutect2, varscan2
- MIB1 | c.903C>T p.G301= | Silent (SNP) | VAF 146/1506 reads (10%) | catalogued as COSV99838257; called by muse, mutect2
- MMAA | c.264A>G p.K88= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV99849581; called by muse, mutect2, varscan2
- MOK | c.1029G>A p.P343= | Silent (SNP) | VAF 34/48 reads (71%) | catalogued as rs777333181, COSV51964762; called by muse, mutect2, varscan2
- MORC2 | c.2604C>T p.G868= (on ENST00000397641 / NM_001303256.3; = p.G806= on NM_014941.3) | Silent (SNP) | VAF 60/89 reads (67%) | catalogued as rs146132479; called by muse, mutect2, varscan2
- MYBPC1 | c.1008C>T p.F336= (on ENST00000550270 / NM_206820.2; = p.F361= on NM_002465.4) | Silent (SNP) | VAF 64/147 reads (44%) | catalogued as rs576268580, COSV62258469; called by muse, mutect2, varscan2
- MYH3 | c.5766C>T p.R1922= | Silent (SNP) | VAF 129/177 reads (73%) | catalogued as rs1195136750, COSV99877595; called by muse, mutect2, varscan2
- MYO18B | c.1401C>T p.S467= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as COSV59145985; called by muse, mutect2, varscan2
- NCAM1 | c.1911C>T p.D637= (on ENST00000316851 / NM_181351.5; = p.D627= on NM_000615.7) | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as rs782154158, COSV57523655; called by muse, mutect2, varscan2
- NCDN | c.1515C>T p.H505= | Silent (SNP) | VAF 124/181 reads (69%) | catalogued as rs150386507; called by muse, mutect2, varscan2
- NCK2 | c.771C>T p.D257= | Silent (SNP) | VAF 30/37 reads (81%) | catalogued as COSV51892404, COSV51894001, COSV99255061; called by muse, mutect2, varscan2
- NCKAP5 | c.4041C>T p.S1347= | Silent (SNP) | VAF 40/45 reads (89%) | catalogued as rs566601823, COSV58427650; called by muse, mutect2, varscan2
- NMT2 | c.1158G>A p.T386= | Silent (SNP) | VAF 210/351 reads (60%) | catalogued as rs376515523, COSV100975454; called by muse, mutect2, varscan2
- NOC2L | c.2106C>T p.D702= | Silent (SNP) | VAF 10/13 reads (77%) | catalogued as rs371539737, COSV100497791; called by muse, mutect2, varscan2
- NOS1 | c.2667C>T p.L889= | Silent (SNP) | VAF 37/151 reads (25%) | catalogued as rs148369257, COSV100499897; called by muse, mutect2, varscan2
- NPTX1 | c.1026G>A p.A342= | Silent (SNP) | VAF 21/26 reads (81%) | catalogued as rs370572568; called by muse, mutect2, varscan2
- NR2C2 | c.879C>T p.N293= (on ENST00000393102; = p.N312= on NM_003298.5) | Silent (SNP) | VAF 67/95 reads (71%) | catalogued as rs750903817, COSV100038213; called by muse, mutect2, varscan2
- NRXN2 | c.3240C>T p.A1080= | Silent (SNP) | VAF 124/161 reads (77%) | catalogued as rs915456390, COSV99632174; called by muse, mutect2, varscan2
- NT5C1A | c.357C>T p.D119= | Silent (SNP) | VAF 11/16 reads (69%) | catalogued as rs756089533, COSV52497275; called by muse, mutect2, varscan2
- OLFM1 | c.234C>T p.V78= (on ENST00000371793 / NM_001282611.2; = p.V60= on NM_006334.4) | Silent (SNP) | VAF 25/42 reads (60%) | catalogued as rs771177279, COSV52962139; called by muse, mutect2, varscan2
- OR1J1 | c.135C>T p.I45= | Silent (SNP) | VAF 419/571 reads (73%) | catalogued as rs746125807, COSV99403050; called by muse, mutect2, varscan2
- OR4C6 | c.570C>A p.T190= | Silent (SNP) | VAF 12/246 reads (5%) | called by muse, mutect2
- PARP8 | c.1029C>T p.S343= | Silent (SNP) | VAF 88/192 reads (46%) | catalogued as COSV99889764; called by muse, mutect2, varscan2
- PCDHA13 | c.1623C>T p.G541= | Silent (SNP) | VAF 20/254 reads (8%) | catalogued as COSV56513205; called by muse, mutect2
- PCDHA4 | c.1671C>T p.D557= | Silent (SNP) | VAF 48/89 reads (54%) | catalogued as rs1451689285, COSV63545662; called by muse, mutect2, varscan2
- PCDHB15 | c.1314C>T p.T438= | Silent (SNP) | VAF 12/107 reads (11%) | catalogued as rs782630330, COSV99178806, COSV99178880; called by muse, mutect2, varscan2
- PCDHGA2 | c.2007C>T p.P669= | Silent (SNP) | VAF 10/124 reads (8%) | catalogued as rs752667791, COSV99528944; called by muse, mutect2
- PCDHGA8 | c.2289G>A p.S763= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as rs766050798, COSV99528954; called by muse, mutect2, varscan2
- PCDHGB1 | c.2121C>T p.I707= | Silent (SNP) | VAF 93/201 reads (46%) | catalogued as COSV99528907; called by muse, mutect2, varscan2
- PDE4D | c.1818C>T p.S606= (on ENST00000340635 / NM_001104631.2; = p.S470= on NM_006203.4) | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as rs368591431, COSV100401734, COSV57720223; called by muse, mutect2, varscan2
- PDIA4 | c.375G>A p.A125= | Silent (SNP) | VAF 22/36 reads (61%) | catalogued as rs535224296, COSV99618211; called by muse, mutect2, varscan2
- PIAS1 | c.1776G>A p.Q592= | Silent (SNP) | VAF 112/163 reads (69%) | catalogued as COSV99986457; called by muse, mutect2, varscan2
- PIK3R2 | c.1089C>T p.G363= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as rs569524771, COSV55846598; called by mutect2, varscan2
- PLXNA3 | c.5232G>A p.T1744= | Silent (SNP) | VAF 23/28 reads (82%) | catalogued as rs782434703, COSV100859783; called by muse, mutect2, varscan2
- POLRMT | c.3546C>T p.D1182= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as rs1220820892, COSV99241161; called by muse, mutect2, varscan2
- POT1 | c.1569G>A p.S523= | Silent (SNP) | VAF 119/266 reads (45%) | catalogued as rs773176095, COSV100713967; ClinVar: likely benign; called by muse, mutect2, varscan2
- PPIL2 | c.606C>T p.A202= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as rs748758994, COSV100622402; called by muse, mutect2, varscan2
- PRKACA | c.882C>T p.N294= | Silent (SNP) | VAF 52/81 reads (64%) | catalogued as rs1021329226, COSV99513642; called by muse, mutect2, varscan2
- PRKACG | c.306G>A p.P102= | Silent (SNP) | VAF 92/167 reads (55%) | catalogued as rs1055295484, COSV99597769; called by muse, mutect2, varscan2
- PRPS2 | c.699G>A p.A233= | Silent (SNP) | VAF 519/632 reads (82%) | catalogued as rs1209257884, COSV66180323; called by muse, mutect2, varscan2
- PTPRH | c.990C>T p.Y330= | Silent (SNP) | VAF 212/289 reads (73%) | catalogued as rs771110471, COSV54743956; called by muse, mutect2, varscan2
- RPS6KC1 | c.882C>T p.A294= | Silent (SNP) | VAF 18/211 reads (9%) | catalogued as rs200954000; called by muse, mutect2
- SELENOO | c.1086C>T p.H362= | Silent (SNP) | VAF 22/28 reads (79%) | catalogued as rs764514579, COSV101096460; called by muse, mutect2, varscan2
- SEMA5A | c.618G>A p.T206= | Silent (SNP) | VAF 95/140 reads (68%) | catalogued as rs552627868, COSV101226844, COSV66804278; called by muse, mutect2, varscan2
- SEMA6A | c.2952G>A p.S984= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as rs372242834; called by muse, varscan2
- SLA | c.30G>A p.A10= (on ENST00000338087 / NM_001045556.3; = p.A50= on NM_006748.4) | Silent (SNP) | VAF 49/230 reads (21%) | catalogued as rs202000953, COSV99598584; called by muse, mutect2, varscan2
- SLC14A2 | c.411C>T p.S137= | Silent (SNP) | VAF 421/1054 reads (40%) | catalogued as rs781158415, COSV99674890; called by muse, mutect2, varscan2
- SLC9A1 | c.2157C>A p.I719= | Silent (SNP) | VAF 17/164 reads (10%) | catalogued as COSV99849209; called by muse, mutect2, varscan2
- SPATA2L | c.1050G>A p.S350= | Silent (SNP) | VAF 7/9 reads (78%) | catalogued as rs778189117, COSV99232038; called by muse, mutect2, varscan2
- SPIRE2 | c.1605G>A p.A535= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs760018809, COSV100988689; called by muse, mutect2, varscan2
- SPTA1 | c.2160C>T p.A720= | Silent (SNP) | VAF 39/58 reads (67%) | catalogued as rs199815523, COSV63749523; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TGIF2LX | c.111C>T p.N37= | Silent (SNP) | VAF 29/47 reads (62%) | catalogued as COSV52213361; called by muse, mutect2, varscan2
- TICRR | c.822G>A p.P274= | Silent (SNP) | VAF 77/97 reads (79%) | catalogued as rs757210629, COSV99175982; called by muse, mutect2, varscan2
- TIMD4 | c.564T>C p.I188= | Silent (SNP) | VAF 51/590 reads (9%) | catalogued as COSV99192473; called by muse, mutect2
- TLL2 | c.969C>T p.G323= | Silent (SNP) | VAF 39/188 reads (21%) | catalogued as rs748603556, COSV63574535; called by muse, mutect2, varscan2
- TLR8 | c.2505G>A p.T835= (on ENST00000218032 / NM_138636.5; = p.T853= on NM_016610.4) | Silent (SNP) | VAF 166/219 reads (76%) | catalogued as rs755564064, COSV54319363; called by muse, mutect2, varscan2
- TMEM131L | c.1998G>A p.T666= | Silent (SNP) | VAF 188/270 reads (70%) | catalogued as rs139178967, COSV99546618; called by muse, mutect2, varscan2
- TMEM132D | c.687C>T p.T229= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs1031888204, COSV101395933, COSV70603640; called by muse, mutect2, varscan2
- TMEM91 | c.336C>T p.I112= | Silent (SNP) | VAF 346/493 reads (70%) | catalogued as rs915622150, COSV55372260; called by muse, mutect2, varscan2
- TNPO2 | c.846C>T p.A282= | Silent (SNP) | VAF 85/134 reads (63%) | catalogued as rs375544397, COSV100790267; called by muse, mutect2, varscan2
- TOM1 | c.381G>A p.A127= | Silent (SNP) | VAF 220/313 reads (70%) | catalogued as rs143199209, COSV101146418; called by muse, mutect2, varscan2
- TOM1L2 | c.1290G>A p.A430= (on ENST00000379504 / NM_001350333.2; = p.A380= on NM_001033551.3) | Silent (SNP) | VAF 75/91 reads (82%) | catalogued as rs141301017; called by muse, mutect2, varscan2
- TPO | c.711C>T p.I237= | Silent (SNP) | VAF 31/42 reads (74%) | catalogued as rs756113203, COSV61101342; called by muse, mutect2, varscan2
- TRIO | c.4890C>T p.D1630= | Silent (SNP) | VAF 163/448 reads (36%) | catalogued as rs780909267, COSV60083039; called by muse, mutect2, varscan2
- TRPM6 | c.4608C>T p.F1536= | Silent (SNP) | VAF 105/153 reads (69%) | catalogued as rs138213738; called by muse, mutect2, varscan2
- TRRAP | c.5238C>T p.I1746= (on ENST00000359863 / NM_001244580.1; = p.I1728= on NM_003496.3) | Silent (SNP) | VAF 47/103 reads (46%) | catalogued as rs782129928, COSV100721786; called by muse, mutect2, varscan2
- TSHZ3 | c.723C>T p.D241= | Silent (SNP) | VAF 466/653 reads (71%) | catalogued as rs772707105, COSV99550423; called by muse, mutect2, varscan2
- TSPAN9 | c.408C>T p.N136= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as rs766796551, COSV50724342; called by muse, mutect2, varscan2
- TULP4 | c.321C>T p.F107= | Silent (SNP) | VAF 12/122 reads (10%) | catalogued as rs1350527922, COSV65579015; called by muse, mutect2, varscan2
- UBTF | c.2211C>T p.D737= | Silent (SNP) | VAF 17/24 reads (71%) | catalogued as rs376920092, COSV100255725; called by muse, mutect2, varscan2
- UMODL1 | c.2694C>T p.Y898= (on ENST00000408910 / NM_001004416.2; = p.Y1026= on NM_173568.3) | Silent (SNP) | VAF 101/242 reads (42%) | catalogued as rs762010917, COSV68569526; called by muse, mutect2, varscan2
- USP20 | c.1242C>T p.P414= | Silent (SNP) | VAF 21/28 reads (75%) | catalogued as rs763873769, COSV59618196; called by muse, mutect2, varscan2
- WNT5B | c.612C>T p.A204= | Silent (SNP) | VAF 13/21 reads (62%) | catalogued as COSV100148530; called by muse, mutect2, varscan2
- ZBTB21 | c.2034G>A p.A678= | Silent (SNP) | VAF 73/177 reads (41%) | catalogued as rs746169227, COSV60405302; called by muse, mutect2, varscan2
- ZMIZ2 | c.1752C>T p.N584= | Silent (SNP) | VAF 42/102 reads (41%) | catalogued as rs552285074, COSV54806022; called by muse, mutect2, varscan2
- ZNF266 | c.1518G>A p.S506= | Silent (SNP) | VAF 106/156 reads (68%) | catalogued as rs764291227, COSV100749305; called by muse, mutect2, varscan2
- ZNF516 | c.1104G>A p.P368= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs1291106503, COSV101487181; called by muse, mutect2, varscan2
- ZNF592 | c.3312C>T p.D1104= | Silent (SNP) | VAF 112/178 reads (63%) | catalogued as rs373997574; called by muse, mutect2, varscan2
- ZNF697 | c.360C>T p.D120= | Silent (SNP) | VAF 9/12 reads (75%) | catalogued as COSV101359976; called by muse, mutect2, varscan2
- ZNRF3 | c.870G>A p.T290= (on ENST00000544604 / NM_001206998.2; = p.T190= on NM_032173.3) | Silent (SNP) | VAF 59/78 reads (76%) | catalogued as rs946206635, COSV60435304; called by muse, mutect2, varscan2
- ZNRF3 | c.1038G>A p.A346= (on ENST00000544604 / NM_001206998.2; = p.A246= on NM_032173.3) | Silent (SNP) | VAF 40/53 reads (75%) | catalogued as rs773344855, COSV60432024; called by muse, mutect2, varscan2
- AMDHD2 | c.*1010del | 3'UTR (DEL) | VAF 13/42 reads (31%) | called by mutect2, pindel, varscan2
- CEP295 | chr11:93733582 C>T | 3'Flank (SNP) | VAF 55/85 reads (65%) | catalogued as rs771583838; called by muse, mutect2, varscan2
- CTBP2 | c.58+12550G>A | Intron (SNP) | VAF 5/9 reads (56%) | catalogued as COSV100456046; called by muse, mutect2, varscan2
- DYRK1A | c.-2C>T | 5'UTR (SNP) | VAF 94/294 reads (32%) | catalogued as rs139696803; called by muse, mutect2, varscan2
- FAM8A1 | c.*8del | 3'UTR (DEL) | VAF 26/72 reads (36%) | catalogued as rs762584146; called by pindel, varscan2
- NVL | c.2183-6718del | Intron (DEL) | VAF 10/12 reads (83%) | catalogued as rs573934358; called by mutect2, varscan2
- PHACTR4 | c.1816+669G>T | Intron (SNP) | VAF 209/261 reads (80%) | catalogued as COSV100868388; called by muse, mutect2, varscan2
- SLC25A3 | c.645-84G>A | Intron (SNP) | VAF 12/168 reads (7%) | catalogued as rs748332641; called by muse, mutect2
